Somatic mutation profile of tumor specimen 0DU07T from CCDI case PBCKLL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.1 years (2,584 days).
Specimen 0DU07T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06853112-ab71-411f-8e8f-a8189ffc2575.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU07O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63a18ea9-263a-496e-8206-42195db5c696

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 264/665 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 182/519 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 91/599 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CYP26A1 | c.1162A>T p.I388F | Missense Mutation (SNP) | VAF 138/544 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56418139; called by muse, mutect2, varscan2
- FBXO31 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 151/389 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV61147898; called by muse, mutect2, varscan2
- CD96 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 247/646 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPS1 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 272/701 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PARP4 | c.2480G>A p.S827N | Missense Mutation (SNP) | VAF 213/527 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTL9 | c.2730G>A p.M910I | Missense Mutation (SNP) | VAF 184/514 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DOT1L | c.3390+96T>C | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as rs1041606935; called by muse, mutect2
- MATN2 | c.2815+49T>C | Intron (SNP) | VAF 102/293 reads (35%) | catalogued as rs778497027; called by muse, mutect2, varscan2
- TCOF1 | c.2859+89T>C | Intron (SNP) | VAF 8/96 reads (8%) | catalogued as rs1219055826, COSV60353458; called by muse, mutect2
